Somatic mutation profile of tumor specimen ALCH-B3ZH-TTP1-A (aliquot ALCH-B3ZH-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B3ZH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.4 years (21,701 days).
Specimen ALCH-B3ZH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d55404a-8a0b-47f0-a6d2-9e52bb898a38.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3ZH-NB1-A (Blood Derived Normal), aliquot ALCH-B3ZH-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a65968c-d628-49dd-830d-7b96bac9caee

The open-access MAF lists 194 somatic variants for this specimen: 140 protein-altering or splice-affecting, 33 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 122, Silent 33, Nonsense Mutation 13, RNA 7, Intron 5, 3'UTR 3, Splice Site 3, 3'Flank 3, 5'UTR 2, Splice Region 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 35/318 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ALAS2 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs757533942; called by muse, mutect2
- ANK2 | c.3032G>C p.R1011P | Missense Mutation (SNP) | VAF 33/494 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV52144383; called by muse, mutect2
- ANK2 | c.11804G>T p.G3935V | Missense Mutation (SNP) | VAF 30/593 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); catalogued as COSV104387159; called by muse, mutect2
- ARHGAP35 | c.3966G>T p.K1322N | Missense Mutation (SNP) | VAF 34/374 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101351586; called by muse, mutect2
- ARHGEF25 | c.855C>A p.N285K | Missense Mutation (SNP) | VAF 22/346 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as rs995795606; called by muse, mutect2
- ASB2 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as rs750583189; called by muse, mutect2
- CAPN11 | c.86C>A p.A29E | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.184); catalogued as rs901085653, COSV67239482; called by muse, mutect2
- CD86 | c.847G>T p.G283* (on ENST00000330540 / NM_175862.5; = p.G277* on NM_006889.4) | Nonsense Mutation (SNP) | VAF 22/555 reads (4%) | catalogued as COSV100054009; called by muse, mutect2
- DDX41 | c.164G>T p.R55L | Missense Mutation (SNP) | VAF 11/322 reads (3%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as rs1479333618; called by muse, mutect2
- DIO2 | c.670G>T p.G224W | Missense Mutation (SNP) | VAF 15/484 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV70444970, COSV70445363; called by muse, mutect2
- DPYS | c.883C>A p.H295N | Missense Mutation (SNP) | VAF 32/410 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as rs374371607; called by muse, mutect2
- EZHIP | c.196G>T p.G66C | Missense Mutation (SNP) | VAF 32/326 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as COSV100539867, COSV57954947, COSV57956805; called by muse, mutect2, varscan2
- FAT1 | c.4105G>T p.E1369* | Nonsense Mutation (SNP) | VAF 22/478 reads (5%) | catalogued as rs1206996841; called by muse, mutect2
- GP6 | c.896G>T p.R299L | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs781050416; called by muse, mutect2
- GPR37 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV58258968; called by muse, mutect2
- HOXA4 | c.838A>G p.K280E | Missense Mutation (SNP) | VAF 36/631 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1277407361; called by muse, mutect2
- HUWE1 | c.298A>T p.T100S | Missense Mutation (SNP) | VAF 16/279 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53333445; called by muse, mutect2
- KRT75 | c.419C>A p.P140H | Missense Mutation (SNP) | VAF 20/360 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52873908; called by muse, mutect2
- LHX8 | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 12/330 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs943066714; called by muse, mutect2
- MAGEA3 | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 19/559 reads (3%) | catalogued as COSV64756301; called by muse, mutect2
- MECP2 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 9/228 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs782638331, COSV57653080; called by muse, mutect2
- NENF | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 34/368 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs753436517; called by muse, mutect2
- NIBAN2 | c.1078G>T p.E360* | Nonsense Mutation (SNP) | VAF 18/179 reads (10%) | catalogued as COSV64824426; called by muse, mutect2
- NOBOX | c.158G>C p.S53T | Missense Mutation (SNP) | VAF 18/608 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV56193545; called by muse, mutect2
- NRXN1 | c.3376T>C p.Y1126H | Missense Mutation (SNP) | VAF 8/220 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100452783; called by muse, mutect2
- OR5P3 | c.412C>A p.P138T | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs768412010; called by muse, mutect2
- PCDHA5 | c.2188G>T p.V730L | Missense Mutation (SNP) | VAF 20/366 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs1554129675, COSV65354574, COSV65358647; called by muse, mutect2
- PPM1A | c.371G>C p.R124T | Missense Mutation (SNP) | VAF 18/502 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.203); catalogued as COSV100349453; called by muse, mutect2
- RNF6 | c.1810C>T p.R604C | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs148001412, COSV60419631; called by muse, mutect2
- SERPINA6 | c.695C>A p.P232H | Missense Mutation (SNP) | VAF 16/547 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1426136858; called by muse, mutect2
- SLC22A12 | c.577G>T p.A193S | Missense Mutation (SNP) | VAF 32/488 reads (7%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.542); catalogued as rs771103495; called by muse, mutect2
- SLC26A11 | c.614G>T p.G205V | Missense Mutation (SNP) | VAF 24/297 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs868740135; called by muse, mutect2
- SLC35G4 | c.611C>A p.S204Y | Missense Mutation (SNP) | VAF 15/237 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs1467138546; called by muse, mutect2
- SPATA31D1 | c.3827C>T p.T1276I | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs1217550524; called by muse, mutect2
- TAS2R39 | c.718C>G p.L240V | Missense Mutation (SNP) | VAF 15/193 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.457); catalogued as rs1222000630; called by muse, mutect2
- TBL1X | c.927C>G p.D309E | Missense Mutation (SNP) | VAF 42/494 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54276148; called by muse, mutect2
- TPO | c.375C>A p.S125R | Missense Mutation (SNP) | VAF 26/606 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs1424856175; called by muse, mutect2
- TRO | c.917C>A p.A306D | Missense Mutation (SNP) | VAF 23/491 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV51507970, COSV99437203; called by muse, mutect2
- ZIM3 | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 16/266 reads (6%) | catalogued as COSV54142916; called by muse, mutect2
- ZXDA | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1223366178; called by muse, mutect2
- ABT1 | c.495G>T p.Q165H | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.075); called by muse, mutect2
- ACTN2 | c.2476G>T p.D826Y | Missense Mutation (SNP) | VAF 36/706 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADD2 | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 13/381 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ALX4 | c.709C>A p.H237N | Missense Mutation (SNP) | VAF 12/323 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.33); called by muse, mutect2
- AMER1 | c.3211C>A p.P1071T | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- AMER3 | c.115G>C p.V39L | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2
- AP1M1 | c.547-2A>T p.X183_splice | Splice Site (SNP) | VAF 6/122 reads (5%) | called by muse, mutect2
- APOB | c.3943A>G p.T1315A | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.214); called by muse, mutect2
- ARHGAP6 | c.411G>T p.W137C | Missense Mutation (SNP) | VAF 42/294 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.533); called by muse, varscan2
- ARMC3 | c.2029A>T p.K677* | Nonsense Mutation (SNP) | VAF 7/136 reads (5%) | called by muse, mutect2
- ATP6V0D2 | c.401G>T p.R134L | Missense Mutation (SNP) | VAF 9/255 reads (4%) | SIFT tolerated (0.73); PolyPhen benign (0.107); called by muse, mutect2
- BAIAP3 | c.1349C>G p.S450* | Nonsense Mutation (SNP) | VAF 16/330 reads (5%) | called by muse, mutect2
- CA8 | c.363A>T p.R121S | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.242); called by muse, mutect2
- CACNA1H | c.2209G>T p.G737C | Missense Mutation (SNP) | VAF 40/308 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- CASP10 | c.348A>G p.R116= | Splice Region (SNP) | VAF 20/564 reads (4%) | called by muse, mutect2
- CCDC63 | c.337C>A p.L113M | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0.006); called by muse, mutect2
- CCDC63 | c.1114C>G p.H372D | Missense Mutation (SNP) | VAF 20/320 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- CDC14C | c.633C>A p.F211L (on ENST00000428251; = p.F104L on NM_152627.3) | Missense Mutation (SNP) | VAF 11/298 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.061); called by muse, mutect2
- CDC34 | c.116A>G p.Y39C | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- CHST8 | c.365C>A p.A122E | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT tolerated (0.81); PolyPhen benign (0.095); called by muse, mutect2
- COQ4 | c.558G>T p.E186D | Missense Mutation (SNP) | VAF 43/423 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CPLX1 | c.28G>C p.G10R | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- CRB1 | c.2924A>T p.N975I | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CRB2 | c.2639C>A p.A880D | Missense Mutation (SNP) | VAF 33/312 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- CSMD3 | c.8197G>C p.G2733R | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CTSW | c.284C>G p.T95R | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DHX9 | c.1906C>G p.L636V | Missense Mutation (SNP) | VAF 21/316 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.241); called by muse, mutect2
- EBF1 | c.1399C>A p.P467T | Missense Mutation (SNP) | VAF 28/275 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- EPS8L1 | c.2086-2A>T p.X696_splice (on ENST00000201647 / NM_133180.3; = p.X569_splice on NM_017729.3) | Splice Site (SNP) | VAF 24/416 reads (6%) | called by muse, mutect2
- FGD3 | c.2033A>T p.K678M | Missense Mutation (SNP) | VAF 14/458 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); called by muse, mutect2
- FLI1 | c.364A>T p.R122W | Missense Mutation (SNP) | VAF 36/452 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- FMO3 | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 8/204 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- GOLGA6L2 | c.424G>T p.A142S | Missense Mutation (SNP) | VAF 24/420 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- GPIHBP1 | c.444C>G p.D148E | Missense Mutation (SNP) | VAF 47/383 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- GPR26 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- HABP2 | c.1630A>C p.T544P | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.089); called by muse, mutect2
- HCN1 | c.683C>A p.S228* | Nonsense Mutation (SNP) | VAF 10/210 reads (5%) | called by muse, mutect2
- HEPH | c.3445G>T p.D1149Y (on ENST00000343002; = p.D882Y on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/231 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- HIPK3 | c.2779A>T p.S927C | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ITIH4 | c.2564A>G p.E855G | Missense Mutation (SNP) | VAF 11/274 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.288); called by muse, mutect2
- ITLN1 | c.761T>A p.M254K | Missense Mutation (SNP) | VAF 27/242 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- KCNA5 | c.1713G>T p.E571D | Missense Mutation (SNP) | VAF 17/257 reads (7%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); called by muse, mutect2
- KIAA1671 | c.230T>G p.V77G | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.037); called by muse, mutect2
- KIR3DL1 | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 24/528 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); called by muse, mutect2
- KRT75 | c.418C>A p.P140T | Missense Mutation (SNP) | VAF 20/360 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- KRTAP29-1 | c.129G>T p.W43C | Missense Mutation (SNP) | VAF 17/427 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- LIPE | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LPA | c.172C>A p.H58N | Missense Mutation (SNP) | VAF 15/413 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- LRP1B | c.8408A>T p.N2803I | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); called by muse, mutect2
- MAN1A1 | c.1836-2A>G p.X612_splice | Splice Site (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- MARVELD1 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 18/406 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0.013); called by muse, mutect2
- MRPS34 | c.570G>T p.M190I | Missense Mutation (SNP) | VAF 18/350 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2
- MUC16 | c.42239A>C p.N14080T | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2
- MYO18B | c.7394A>G p.Q2465R | Missense Mutation (SNP) | VAF 14/333 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- NACAD | c.753G>T p.W251C | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- NLRC4 | c.73G>C p.D25H | Missense Mutation (SNP) | VAF 16/382 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- NMUR1 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 23/279 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- NRG3 | c.2077C>A p.P693T (on ENST00000404547 / NM_001370084.1; = p.P669T on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/430 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2
- NRXN1 | c.1631A>T p.E544V | Missense Mutation (SNP) | VAF 12/313 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- NSUN5 | c.634G>T p.D212Y | Missense Mutation (SNP) | VAF 27/497 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OAZ1 | c.43T>A p.F15I | Missense Mutation (SNP) | VAF 11/268 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR4A47 | c.437C>A p.S146Y | Missense Mutation (SNP) | VAF 15/176 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- PABPC5 | c.1075G>C p.D359H | Missense Mutation (SNP) | VAF 14/345 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.112); called by muse, mutect2
- PAX1 | c.1420C>T p.Q474* | Nonsense Mutation (SNP) | VAF 12/342 reads (4%) | called by muse, mutect2
- PCDHB15 | c.2183C>T p.P728L | Missense Mutation (SNP) | VAF 21/370 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.197); called by muse, mutect2
- POLRMT | c.919G>T p.G307W | Missense Mutation (SNP) | VAF 8/214 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- POTEJ | c.316C>A p.L106I | Missense Mutation (SNP) | VAF 16/491 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.061); called by muse, mutect2
- PPP4R3C | c.1741C>A p.L581I | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.322); called by muse, mutect2
- PRAMEF8 | c.1019C>A p.T340K | Missense Mutation (SNP) | VAF 34/728 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- PTCH1 | c.502A>C p.N168H | Missense Mutation (SNP) | VAF 13/385 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- PTF1A | c.908C>A p.P303Q | Missense Mutation (SNP) | VAF 27/656 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PTPRO | c.3387A>T p.K1129N (on ENST00000281171 / NM_030667.3; = p.K1101N on NM_002848.4) | Missense Mutation (SNP) | VAF 32/386 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.355); called by muse, mutect2
- PXDN | c.3798G>T p.K1266N | Missense Mutation (SNP) | VAF 20/398 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- RAG1 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 12/378 reads (3%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- RBM10 | c.193A>T p.S65C | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2
- RP1 | c.2420C>A p.S807Y | Missense Mutation (SNP) | VAF 14/167 reads (8%) | SIFT tolerated (0.98); PolyPhen benign (0.014); called by muse, mutect2
- RYR2 | c.9222C>A p.N3074K | Missense Mutation (SNP) | VAF 20/407 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); called by muse, mutect2
- SALL3 | c.3154C>A p.L1052M | Missense Mutation (SNP) | VAF 30/460 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.733); called by muse, mutect2
- SERPINA5 | c.767G>T p.G256V | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.962); called by muse, mutect2
- SH3BP4 | c.2564A>T p.Q855L | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- SLC41A3 | c.1309G>T p.A437S | Missense Mutation (SNP) | VAF 19/418 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.254); called by muse, mutect2
- SLC4A3 | c.2224G>T p.E742* | Nonsense Mutation (SNP) | VAF 26/402 reads (6%) | called by muse, mutect2
- SLC9A6 | c.1473G>T p.W491C | Missense Mutation (SNP) | VAF 14/373 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- SLCO1C1 | c.404A>G p.Q135R | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SMIM23 | c.400C>A p.Q134K | Missense Mutation (SNP) | VAF 35/321 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SORL1 | c.6576G>A p.L2192= | Splice Region (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
- SPATC1 | c.1709C>A p.A570E | Missense Mutation (SNP) | VAF 11/205 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- SSH1 | c.1038T>A p.D346E | Missense Mutation (SNP) | VAF 19/321 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.421); called by muse, mutect2
- TGIF2LX | c.475C>A p.L159M | Missense Mutation (SNP) | VAF 59/847 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.4); called by muse, mutect2
- TRIM48 | c.147C>A p.S49R | Missense Mutation (SNP) | VAF 42/613 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- TRO | c.1362C>A p.Y454* | Nonsense Mutation (SNP) | VAF 17/355 reads (5%) | called by muse, mutect2
- UBE2I | c.460A>T p.K154* | Nonsense Mutation (SNP) | VAF 22/312 reads (7%) | called by muse, mutect2
- USH1G | c.391C>A p.L131M | Missense Mutation (SNP) | VAF 46/708 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.374); called by muse, mutect2
- UTS2R | c.1018G>T p.G340W | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); called by muse, mutect2
- VMO1 | c.413C>A p.A138E | Missense Mutation (SNP) | VAF 14/460 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- VSX2 | c.281T>C p.L94P | Missense Mutation (SNP) | VAF 12/404 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- ZIM3 | c.212A>T p.E71V | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.133); called by muse, mutect2
- ZNF256 | c.415C>G p.Q139E | Missense Mutation (SNP) | VAF 19/372 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- ZNF775 | c.1456A>T p.K486* | Nonsense Mutation (SNP) | VAF 30/490 reads (6%) | called by muse, mutect2
- ADCY1 | c.939G>T p.T313= | Silent (SNP) | VAF 26/383 reads (7%) | catalogued as COSV52031301, COSV52034722; called by muse, mutect2
- ADNP2 | c.2262C>T p.C754= | Silent (SNP) | VAF 14/190 reads (7%) | called by muse, mutect2
- AHNAK | c.2727A>T p.S909= | Silent (SNP) | VAF 35/472 reads (7%) | called by muse, mutect2
- ARC | c.948G>C p.A316= | Silent (SNP) | VAF 30/310 reads (10%) | called by muse, mutect2
- CACNA1E | c.3105G>T p.L1035= | Silent (SNP) | VAF 22/231 reads (10%) | called by muse, mutect2
- CCDC63 | c.336C>A p.S112= | Silent (SNP) | VAF 6/134 reads (4%) | called by muse, mutect2
- CCNT1 | c.792C>T p.A264= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs754521618; called by mutect2, varscan2
- CDH18 | c.699C>A p.S233= | Silent (SNP) | VAF 47/524 reads (9%) | catalogued as COSV56913934, COSV56961439, COSV56963704; called by muse, mutect2
- CDH6 | c.189G>T p.L63= | Silent (SNP) | VAF 14/354 reads (4%) | catalogued as COSV54066340; called by muse, mutect2
- CEBPA | c.1014G>A p.L338= | Silent (SNP) | VAF 13/320 reads (4%) | called by muse, mutect2
- CELSR1 | c.6588C>T p.A2196= | Silent (SNP) | VAF 14/160 reads (9%) | catalogued as COSV99418879; called by muse, mutect2
- CHRNB3 | c.843G>T p.V281= | Silent (SNP) | VAF 5/87 reads (6%) | called by muse, mutect2
- COL9A3 | c.666G>T p.P222= | Silent (SNP) | VAF 16/179 reads (9%) | catalogued as COSV59652209; called by muse, mutect2
- EXTL1 | c.903C>A p.P301= | Silent (SNP) | VAF 20/193 reads (10%) | called by muse, mutect2, varscan2
- FGF16 | c.492C>A p.A164= | Silent (SNP) | VAF 18/408 reads (4%) | called by muse, mutect2
- FTHL17 | c.117C>A p.A39= | Silent (SNP) | VAF 48/430 reads (11%) | called by muse, mutect2, varscan2
- GAB3 | c.405C>A p.P135= | Silent (SNP) | VAF 16/414 reads (4%) | called by muse, mutect2
- INTS1 | c.1794C>T p.P598= | Silent (SNP) | VAF 13/174 reads (7%) | catalogued as rs372005241; called by muse, mutect2
- KMT2A | c.10119A>G p.P3373= | Silent (SNP) | VAF 14/206 reads (7%) | catalogued as rs1056247424; called by muse, mutect2
- KMT2D | c.3993A>G p.S1331= | Silent (SNP) | VAF 14/243 reads (6%) | called by muse, mutect2
- NSUN5 | c.633G>A p.Q211= | Silent (SNP) | VAF 26/501 reads (5%) | called by muse, mutect2
- OGFR | c.1371G>A p.K457= | Silent (SNP) | VAF 17/309 reads (6%) | called by muse, mutect2
- OR10H1 | c.222C>T p.T74= | Silent (SNP) | VAF 6/93 reads (6%) | catalogued as rs1320535487, COSV58472390; called by muse, mutect2
- PIP4K2A | c.42C>T p.S14= | Silent (SNP) | VAF 15/340 reads (4%) | called by muse, mutect2
- PLXNA3 | c.3471C>A p.G1157= | Silent (SNP) | VAF 7/179 reads (4%) | called by muse, mutect2
- PRMT8 | c.636G>T p.G212= | Silent (SNP) | VAF 21/404 reads (5%) | called by muse, mutect2
- PSPN | c.402C>T p.F134= | Silent (SNP) | VAF 11/108 reads (10%) | called by muse, mutect2, varscan2
- RET | c.144G>T p.T48= | Silent (SNP) | VAF 39/398 reads (10%) | catalogued as COSV60705166; called by muse, mutect2, varscan2
- TNRC6C | c.3405C>T p.N1135= | Silent (SNP) | VAF 20/342 reads (6%) | called by muse, mutect2
- TTN | c.97035C>A p.V32345= (on ENST00000591111; = p.V24921= on NM_003319.4) | Silent (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- YY2 | c.183G>T p.V61= | Silent (SNP) | VAF 8/213 reads (4%) | called by muse, mutect2
- ZFP57 | c.1284C>A p.V428= | Silent (SNP) | VAF 38/587 reads (6%) | catalogued as COSV65305875, COSV65306329; called by muse, mutect2
- ZNRF4 | c.225G>T p.R75= | Silent (SNP) | VAF 15/141 reads (11%) | catalogued as rs1377529654; called by muse, mutect2, varscan2
- AC012236.1 | n.73C>A | RNA (SNP) | VAF 14/254 reads (6%) | called by muse, mutect2
- ALDH2 | c.-14G>T | 5'UTR (SNP) | VAF 42/356 reads (12%) | called by muse, varscan2
- CLU | c.*98T>A | 3'UTR (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- CNBD1 | c.*41T>A | 3'UTR (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- CPLANE1 | c.*566G>T | 3'UTR (SNP) | VAF 21/199 reads (11%) | called by muse, varscan2
- DCHS2 | n.1871G>A | RNA (SNP) | VAF 16/167 reads (10%) | catalogued as rs1021249280, COSV59733500; called by muse, mutect2
- ERCC3 | c.28+84C>T | Intron (SNP) | VAF 10/146 reads (7%) | called by muse, mutect2
- FAM86DP | n.326G>T | RNA (SNP) | VAF 22/418 reads (5%) | called by muse, mutect2
- FBXW9 | chr19:12689207 C>A | 3'Flank (SNP) | VAF 16/350 reads (5%) | called by muse, mutect2
- IGKV1D-16 | c.-14A>G | 5'UTR (SNP) | VAF 22/387 reads (6%) | catalogued as rs1315522795; called by muse, mutect2
- KDM5C | c.2622+16G>T | Intron (SNP) | VAF 20/510 reads (4%) | called by muse, mutect2
- LINC01101 | n.508C>A | RNA (SNP) | VAF 26/308 reads (8%) | catalogued as rs1195993954; called by muse, mutect2
- MIR1197 | n.27G>T | RNA (SNP) | VAF 8/228 reads (4%) | called by muse, mutect2
- MIR6511A3 | chr16:16371635 A>T | 3'Flank (SNP) | VAF 45/630 reads (7%) | called by muse, mutect2
- MS4A18 | chr11:60743939 G>T | 3'Flank (SNP) | VAF 11/216 reads (5%) | called by muse, mutect2
- NRIR | chr2:6840575 C>A | 5'Flank (SNP) | VAF 7/177 reads (4%) | called by muse, mutect2
- PLEKHM1P1 | n.846G>C | RNA (SNP) | VAF 20/309 reads (6%) | called by muse, mutect2
- RPH3A | c.1776-57G>C | Intron (SNP) | VAF 14/185 reads (8%) | called by muse, mutect2
- SERPINA6 | c.613+127C>T | Intron (SNP) | VAF 14/198 reads (7%) | catalogued as rs766524154; called by muse, mutect2
- SHOC2 | c.841+3172G>T | Intron (SNP) | VAF 7/159 reads (4%) | called by muse, mutect2
- TMEM183B | n.51C>A | RNA (SNP) | VAF 20/395 reads (5%) | called by muse, mutect2
